CCDI case PBBTTH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7a612b95-3d08-4ec2-a532-a0968f401763

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.7 years (3,557 days).

Biospecimens (3 samples)
- Sample 0DGO9X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGOAW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGOB0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
